Somatic mutation profile of tumor specimen TCGA-DD-A115-01A (aliquot TCGA-DD-A115-01A-11D-A12Z-10) from TCGA case TCGA-DD-A115, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 53.9 years (19,697 days).
Specimen TCGA-DD-A115-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f59013e8-3ca1-47f3-bcf8-888945402364.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DD-A115-10A (Blood Derived Normal), aliquot TCGA-DD-A115-10A-01D-A12Z-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4df4831c-7af6-4268-8818-2f3abf446465

The open-access MAF lists 96 somatic variants for this specimen: 71 protein-altering or splice-affecting, 22 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 22, Frame Shift Del 4, Splice Site 4, Nonsense Mutation 3, Intron 1, Frame Shift Ins 1, Splice Region 1, Translation Start Site 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC6 | c.4387G>T p.V1463L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.195); catalogued as COSV52741009; called by muse, mutect2, varscan2
- AHNAK2 | c.5540A>G p.D1847G | Missense Mutation (SNP) | VAF 36/182 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV60906919; called by muse, varscan2
- ANKRD26 | c.1315G>T p.G439W | Missense Mutation (SNP) | VAF 41/107 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.984); catalogued as COSV65792673; called by muse, mutect2, varscan2
- ANXA3 | c.252G>A p.M84I | Missense Mutation (SNP) | VAF 55/138 reads (40%) | SIFT tolerated (1); PolyPhen benign (0.144); catalogued as COSV53712986; called by muse, mutect2, varscan2
- AP1G1 | c.179G>T p.G60V | Missense Mutation (SNP) | VAF 47/103 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55493847; called by muse, mutect2, varscan2
- ARHGAP30 | c.3160T>A p.S1054T (on ENST00000368013 / NM_001025598.2; = p.S843T on NM_181720.3) | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV63514686; called by muse, mutect2, varscan2
- ARHGEF28 | c.2684C>T p.P895L | Missense Mutation (SNP) | VAF 45/141 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV55246808; called by muse, mutect2, varscan2
- ATM | c.5302A>G p.R1768G | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.66); catalogued as COSV53724285; called by muse, mutect2, varscan2
- ATP9A | c.167A>T p.N56I | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV58762615; called by muse, mutect2, varscan2
- CACNB4 | c.503G>C p.R168T | Missense Mutation (SNP) | VAF 26/61 reads (43%) | SIFT tolerated (0.18); PolyPhen benign (0.157); catalogued as rs376364352, COSV52405783; called by muse, mutect2, varscan2
- CARD11 | c.361G>C p.E121Q | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV100712270; called by muse, mutect2
- CFAP46 | c.541C>A p.L181I | Missense Mutation (SNP) | VAF 27/39 reads (69%) | SIFT deleterious (0); PolyPhen possibly damaging (0.578); catalogued as COSV63949066; called by muse, mutect2, varscan2
- CLEC4F | c.879G>C p.Q293H | Missense Mutation (SNP) | VAF 18/291 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV55478053; called by muse, mutect2
- CNPY2 | c.89-2A>G p.X30_splice | Splice Site (SNP) | VAF 30/78 reads (38%) | catalogued as COSV56263791; called by muse, mutect2, varscan2
- CPAMD8 | c.3341C>T p.P1114L (on ENST00000651564; = p.P1067L on NM_015692.5) | Missense Mutation (SNP) | VAF 20/49 reads (41%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs200032712, COSV71595723; called by muse, mutect2, varscan2
- DLK2 | c.923T>C p.V308A | Missense Mutation (SNP) | VAF 26/97 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as rs754440464, COSV55084190; called by muse, mutect2
- DNAJC1 | c.1234A>T p.T412S | Missense Mutation (SNP) | VAF 48/144 reads (33%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.991); catalogued as COSV65408746; called by muse, mutect2, varscan2
- DPP3 | c.241G>T p.A81S | Missense Mutation (SNP) | VAF 7/38 reads (18%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV64755790; called by muse, mutect2, varscan2
- ELOA | c.1960G>C p.E654Q | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101403814; called by muse, varscan2
- FCAR | c.70+2T>C p.X24_splice | Splice Site (SNP) | VAF 44/91 reads (48%) | catalogued as COSV62028149; called by muse, mutect2, varscan2
- FRS3 | c.1450C>G p.R484G | Missense Mutation (SNP) | VAF 28/79 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52483880; called by muse, mutect2, varscan2
- GAA | c.2483G>T p.G828V | Missense Mutation (SNP) | VAF 23/62 reads (37%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV56406662; called by muse, mutect2, varscan2
- GCN1 | c.1844A>G p.H615R | Missense Mutation (SNP) | VAF 29/77 reads (38%) | SIFT tolerated (0.35); PolyPhen benign (0.023); catalogued as COSV56103200; called by muse, mutect2, varscan2
- GHR | c.800G>A p.W267* | Nonsense Mutation (SNP) | VAF 49/149 reads (33%) | catalogued as COSV50105754; called by muse, mutect2, varscan2
- GTF2E1 | c.358G>A p.D120N | Missense Mutation (SNP) | VAF 56/106 reads (53%) | SIFT tolerated (0.11); PolyPhen benign (0.047); catalogued as COSV52203037; called by muse, mutect2, varscan2
- GTF3C1 | c.1712C>A p.A571E | Missense Mutation (SNP) | VAF 37/93 reads (40%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV62238752, COSV99050026; called by muse, mutect2, varscan2
- H4C12 | c.1A>C p.M1? | Translation Start Site (SNP) | VAF 29/104 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.007); catalogued as COSV62743668, COSV62743967; called by muse, mutect2, varscan2
- IGLL5 | c.531C>A p.S177R | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.944); catalogued as rs367960872; called by muse, mutect2, varscan2
- KCNJ6 | c.760C>T p.P254S | Missense Mutation (SNP) | VAF 30/161 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55708970; called by muse, mutect2, varscan2
- LINGO2 | c.1228C>A p.P410T | Missense Mutation (SNP) | VAF 16/99 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs199551773, COSV58056464; called by muse, mutect2, varscan2
- MKNK1 | c.883G>A p.A295T | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.61); PolyPhen benign (0.006); catalogued as COSV57860387; called by muse, mutect2, varscan2
- MLXIP | c.2480G>A p.R827Q | Missense Mutation (SNP) | VAF 12/208 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.206); catalogued as rs968950565, COSV59833839; called by muse, mutect2
- MPO | c.997C>T p.L333F | Missense Mutation (SNP) | VAF 22/52 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56560997; called by muse, mutect2, varscan2
- MYO7A | c.188C>G p.S63W | Missense Mutation (SNP) | VAF 22/48 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV68683279; called by muse, mutect2, varscan2
- NAAA | c.302G>T p.G101V | Missense Mutation (SNP) | VAF 19/52 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54431113; called by muse, mutect2, varscan2
- NRK | c.1204C>A p.Q402K | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.01); catalogued as COSV54589156; called by muse, mutect2, varscan2
- OR2B11 | c.178C>A p.H60N | Missense Mutation (SNP) | VAF 32/83 reads (39%) | SIFT deleterious (0.03); PolyPhen benign (0.036); catalogued as COSV100275090; called by muse, mutect2, varscan2
- OR51E2 | c.230T>A p.M77K | Missense Mutation (SNP) | VAF 15/31 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.818); catalogued as COSV67806599; called by muse, mutect2, varscan2
- PCBP1 | c.299T>A p.L100Q | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.96); catalogued as rs1422143141, COSV57849655, COSV57849905, COSV57849936; called by muse, mutect2, varscan2
- PCDHA11 | c.551C>T p.T184I | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.033); catalogued as COSV56475528; called by muse, mutect2, varscan2
- PGK2 | c.1180A>T p.T394S | Missense Mutation (SNP) | VAF 48/99 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as rs1206634317, COSV59162684; called by muse, mutect2, varscan2
- PLA2G7 | c.1195C>G p.H399D | Missense Mutation (SNP) | VAF 132/258 reads (51%) | SIFT tolerated (0.38); PolyPhen benign (0); catalogued as COSV51258313; called by muse, mutect2, varscan2
- PLCB4 | c.2169G>T p.E723D | Missense Mutation (SNP) | VAF 42/103 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as COSV53792031; called by muse, mutect2, varscan2
- PLXND1 | c.5621T>C p.M1874T | Missense Mutation (SNP) | VAF 45/124 reads (36%) | SIFT deleterious (0); PolyPhen benign (0.315); catalogued as COSV60709071; called by muse, mutect2, varscan2
- PSD2 | c.529G>T p.E177* | Nonsense Mutation (SNP) | VAF 46/83 reads (55%) | catalogued as COSV51197032; called by muse, mutect2, varscan2
- RNF10 | c.2254A>T p.N752Y | Missense Mutation (SNP) | VAF 12/101 reads (12%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.556); catalogued as COSV58043337; called by muse, mutect2, varscan2
- RPS6KB1 | c.990A>T p.R330S | Missense Mutation (SNP) | VAF 141/235 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56674960; called by muse, mutect2, varscan2
- SARDH | c.1147C>A p.P383T | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV64095883; called by muse, mutect2, varscan2
- SCAPER | c.337G>A p.A113T | Missense Mutation (SNP) | VAF 80/139 reads (58%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV57733199; called by muse, mutect2, varscan2
- SIGLEC12 | c.1286G>T p.G429V (on ENST00000291707 / NM_053003.4; = p.G311V on NM_033329.2) | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as COSV52459108; called by muse, mutect2, varscan2
- SIRPD | c.358T>C p.F120L | Missense Mutation (SNP) | VAF 21/70 reads (30%) | SIFT tolerated (0.08); PolyPhen benign (0.077); catalogued as COSV67546201; called by muse, mutect2, varscan2
- SLC25A12 | c.721G>T p.G241C | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.894); catalogued as COSV55531331; called by muse, mutect2, varscan2
- SLC2A3 | c.66C>A p.F22L | Missense Mutation (SNP) | VAF 42/127 reads (33%) | SIFT tolerated (0.81); PolyPhen benign (0.028); catalogued as COSV50000145; called by muse, mutect2, varscan2
- STBD1 | c.513G>T p.E171D | Missense Mutation (SNP) | VAF 38/100 reads (38%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as COSV52953322; called by muse, mutect2, varscan2
- STOX1 | c.2948T>C p.L983P | Missense Mutation (SNP) | VAF 68/162 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53812699; called by muse, mutect2, varscan2
- SYCP2L | c.115G>T p.G39* | Nonsense Mutation (SNP) | VAF 62/156 reads (40%) | catalogued as COSV51649638; called by muse, mutect2, varscan2
- TAF1 | c.5312A>G p.H1771R (on ENST00000373790 / NM_138923.4; = p.H1792R on NM_004606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 64/82 reads (78%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0); catalogued as COSV52106841; called by muse, mutect2
- TAS2R39 | c.676C>A p.L226M | Missense Mutation (SNP) | VAF 12/176 reads (7%) | SIFT tolerated (0.29); PolyPhen benign (0.118); catalogued as COSV71470788; called by muse, mutect2
- TIMP4 | c.501del p.C168Vfs*31 | Frame Shift Del (DEL) | VAF 15/73 reads (21%) | catalogued as COSV55138607; called by mutect2, pindel, varscan2
- TNFRSF25 | c.775C>T p.H259Y | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.454); catalogued as COSV61067536; called by muse, mutect2, varscan2
- TRIM71 | c.853-1G>A p.X285_splice | Splice Site (SNP) | VAF 27/171 reads (16%) | catalogued as COSV67470001; called by muse, mutect2, varscan2
- TRMT10C | c.259G>A p.D87N | Missense Mutation (SNP) | VAF 38/107 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV59305083; called by muse, mutect2, varscan2
- YWHAZ | c.280T>A p.C94S | Missense Mutation (SNP) | VAF 12/154 reads (8%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.995); catalogued as COSV62053326; called by muse, mutect2
- ZBTB7B | c.956G>A p.S319N (on ENST00000292176; = p.S353N on NM_001252406.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0.01); catalogued as COSV52691446; called by muse, mutect2, varscan2
- ZNF432 | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 57/149 reads (38%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs749214090, COSV55415260; called by muse, mutect2, varscan2
- ZNF560 | c.449-1G>A p.X150_splice | Splice Site (SNP) | VAF 10/69 reads (14%) | catalogued as COSV56865123; called by muse, mutect2, varscan2
- CEP97 | c.1854dup p.F619Ifs*34 | Frame Shift Ins (INS) | VAF 43/262 reads (16%) | called by pindel, varscan2
- COPS4 | c.306G>A p.Q102= | Splice Region (SNP) | VAF 6/64 reads (9%) | called by mutect2, varscan2
- MTF2 | c.1421del p.Y474Lfs*43 | Frame Shift Del (DEL) | VAF 39/116 reads (34%) | called by mutect2, pindel, varscan2
- OR51A4 | c.192del p.L65Ffs*20 | Frame Shift Del (DEL) | VAF 114/561 reads (20%) | called by mutect2, pindel, varscan2
- RAB40B | c.672del p.F225Sfs*7 | Frame Shift Del (DEL) | VAF 16/120 reads (13%) | called by mutect2, pindel, varscan2
- ABCA13 | c.2376A>G p.K792= | Silent (SNP) | VAF 10/72 reads (14%) | catalogued as rs758110820, COSV70025596, COSV70027005; called by muse, mutect2, varscan2
- ALS2 | c.9A>C p.S3= | Silent (SNP) | VAF 19/65 reads (29%) | catalogued as COSV51883762; called by muse, mutect2, varscan2
- AP1G1 | c.180C>T p.G60= | Silent (SNP) | VAF 47/102 reads (46%) | catalogued as COSV100249956; called by muse, mutect2, varscan2
- BAHCC1 | c.660G>A p.V220= | Silent (SNP) | VAF 8/44 reads (18%) | catalogued as rs1335460508, COSV57022470; called by muse, mutect2, varscan2
- DAPK1 | c.1851G>A p.A617= | Silent (SNP) | VAF 5/15 reads (33%) | catalogued as rs777677048, COSV63783752; called by muse, mutect2, varscan2
- DYNC1H1 | c.3855G>A p.G1285= | Silent (SNP) | VAF 23/61 reads (38%) | catalogued as COSV64134159; called by muse, mutect2, varscan2
- EIF2AK4 | c.1845C>T p.C615= | Silent (SNP) | VAF 28/51 reads (55%) | catalogued as COSV55464625; called by muse, mutect2, varscan2
- EWSR1 | c.1509G>A p.R503= | Silent (SNP) | VAF 20/54 reads (37%) | catalogued as COSV58421359; called by muse, mutect2
- FARP2 | c.192C>T p.C64= | Silent (SNP) | VAF 18/88 reads (20%) | catalogued as rs766643383, COSV50868874; called by muse, mutect2, varscan2
- FUT3 | c.10C>T p.L4= | Silent (SNP) | VAF 12/84 reads (14%) | catalogued as COSV57486038; called by muse, mutect2, varscan2
- GPR84 | c.159C>T p.T53= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as rs143236488, COSV57209197; called by muse, mutect2, varscan2
- HYDIN | c.12213C>A p.V4071= | Silent (SNP) | VAF 12/28 reads (43%) | catalogued as COSV104430560, COSV66636787; called by mutect2, varscan2
- MAP2K6 | c.687C>T p.L229= | Silent (SNP) | VAF 78/138 reads (57%) | catalogued as COSV100765063, COSV63005007; called by muse, mutect2, varscan2
- MRC2 | c.531C>T p.T177= | Silent (SNP) | VAF 33/50 reads (66%) | catalogued as COSV57636319; called by muse, mutect2, varscan2
- MYT1L | c.339C>T p.D113= | Silent (SNP) | VAF 24/469 reads (5%) | catalogued as rs1323553095, COSV67707006; called by muse, mutect2
- NPAS2 | c.672T>C p.V224= | Silent (SNP) | VAF 28/81 reads (35%) | catalogued as COSV59554993; called by muse, mutect2, varscan2
- OR2B11 | c.177C>A p.L59= | Silent (SNP) | VAF 31/83 reads (37%) | catalogued as COSV100275091; called by muse, mutect2, varscan2
- OR2H2 | c.381C>A p.P127= | Silent (SNP) | VAF 44/122 reads (36%) | catalogued as rs1562047505, COSV100589771, COSV63540720; called by muse, varscan2
- SLC10A5 | c.1078C>T p.L360= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as COSV72828206; called by muse, mutect2, varscan2
- SMAP2 | c.27G>A p.V9= | Silent (SNP) | VAF 43/107 reads (40%) | called by muse, mutect2, varscan2
- TBC1D26 | c.453C>T p.H151= | Silent (SNP) | VAF 79/172 reads (46%) | catalogued as rs752787510, COSV68608426; called by muse, mutect2, varscan2
- TRPV5 | c.1242C>T p.R414= | Silent (SNP) | VAF 40/105 reads (38%) | catalogued as COSV54682850; called by muse, varscan2
- CARMIL3 | chr14:24048789 T>C | 5'Flank (SNP) | VAF 169/460 reads (37%) | catalogued as rs759806033; called by muse, mutect2, varscan2
- OBSCN | c.11659+4380G>A | Intron (SNP) | VAF 29/77 reads (38%) | catalogued as COSV99483235; called by muse, mutect2, varscan2
- ZNF137P | n.1622C>T | RNA (SNP) | VAF 4/32 reads (13%) | called by muse, mutect2, varscan2
